MMRF case MMRF_1426 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/98e09af5-db0d-4243-8dbc-3fc40022fae7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.4 years (21,683 days); ISS stage: I; Days to last known disease status: 1,386 days (3.8 years); Days to last follow up: 1,386 days (3.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 59 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 62 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 71 days; Days to treatment end: 92 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 71 days; Days to treatment end: 91 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 122 days; Days to treatment end: 122 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 147 days; Days to treatment end: 147 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 148 days; Days to treatment end: 148 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 2.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.139 mg/dL; Immunoglobulin G 1.78 g/L; Immunoglobulin A 35.2 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 8.8 g/dL; Glucose 4.62 mmol/L.
- Day 99 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.626 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.316 mg/dL; Immunoglobulin G 2.03 g/L; Immunoglobulin A 1.83 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.08 mmol/L; Albumin 36 g/L; Total Protein 5.4 g/dL; Glucose 4.4 mmol/L.
- Day 182: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 1.74 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 11 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.03 mmol/L; Albumin 36 g/L; Total Protein 5.5 g/dL; Glucose 5.01 mmol/L.
- Day 273 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.544 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.262 mg/dL; Immunoglobulin G 2.93 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.05 mmol/L; Albumin 38 g/L; Total Protein 5.7 g/dL; Glucose 4.24 mmol/L.
- Day 372 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.673 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.319 mg/dL; Immunoglobulin G 3.48 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.13 mmol/L; Albumin 39 g/L; Total Protein 5.5 g/dL; Glucose 4.02 mmol/L.
- Day 480 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.678 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 3.59 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 5.8 g/dL; Glucose 4.29 mmol/L.
- Day 700 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.556 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.275 mg/dL; Immunoglobulin G 4.45 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.05 mmol/L; Albumin 43 g/L.
- Day 883 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.684 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.341 mg/dL; Immunoglobulin G 4.62 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.57 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.08 mmol/L; Albumin 43 g/L; Total Protein 6.1 g/dL; Glucose 4.29 mmol/L.
- Day 974 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.516 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.328 mg/dL; Immunoglobulin G 4.29 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.51 g/L; Beta 2 Microglobulin 1.1 µg/mL; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.05 mmol/L; Albumin 40 g/L; Total Protein 5.7 g/dL; Glucose 4.4 mmol/L.
- Day 1,197 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 4.65 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.61 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.1 mmol/L; Albumin 39 g/L.
- Day 1,386 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.75 mg/dL; Immunoglobulin G 5.19 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.61 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 6.55 mmol/L.

Other clinical attributes
- Day 1: Weight: 58 kg; Height: 162 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1426_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1426_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
